Somatic mutation profile of tumor specimen C3N-02030-03 (aliquot CPT0133780092) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3480a69-262e-4f7c-97ce-8b8923f55547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b226469-4687-4a58-982c-9fcc65b8f55c

The open-access MAF lists 677 somatic variants for this specimen: 462 protein-altering or splice-affecting, 133 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 133, Frame Shift Del 86, Intron 50, Frame Shift Ins 25, Nonsense Mutation 19, 3'UTR 10, RNA 7, 5'UTR 6, 3'Flank 6, Splice Site 5, In Frame Del 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 57/143 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 64/158 reads (41%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 68/126 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 54/109 reads (50%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 48/119 reads (40%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ABI3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs770714352; called by muse, mutect2, varscan2
- ACTN4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758778538; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 72/108 reads (67%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 38/83 reads (46%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ALG5 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53504362; called by muse, mutect2, varscan2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 119/266 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATF7IP2 | c.1312del p.I438Lfs*21 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs763946306; called by mutect2, varscan2
- ATP10D | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs773685085, COSV56704660; called by muse, mutect2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- ATRX | c.5081A>T p.N1694I | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64873985; called by muse, mutect2
- AXL | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV99997218; called by muse, mutect2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 62/157 reads (39%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 59/117 reads (50%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CCDC80 | c.1982C>T p.T661I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1559880379, COSV52816132; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4778G>A p.S1593N | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs755709663, COSV62573362; called by muse, mutect2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 10/30 reads (33%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, mutect2, varscan2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 19/42 reads (45%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CRACD | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs776911167, COSV51728777; called by muse, mutect2, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CROCC | c.3604C>T p.R1202* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as COSV65011597; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DIAPH3 | c.3497del p.K1166Rfs*49 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs749399334, COSV100931069; called by mutect2, pindel, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1184501423; called by muse, mutect2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FBP2 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263431898; called by muse, mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 157/364 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 126/325 reads (39%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 47/125 reads (38%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 20/71 reads (28%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- HSD17B4 | c.1679G>A p.C560Y (on ENST00000414835 / NM_001199291.3; = p.C535Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56335900; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- ICE1 | c.6169C>T p.R2057C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1329448263, COSV56822031; called by muse, mutect2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 18/38 reads (47%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KIF26B | c.4157C>A p.P1386H | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63639112; called by muse, mutect2
- KIF2B | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99274473; called by muse, mutect2, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LIN37 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs754704937, COSV50001208; called by muse, mutect2
- LRP2 | c.11013C>T p.C3671= | Splice Region (SNP) | VAF 18/171 reads (11%) | catalogued as rs1436494910, COSV99789716; called by muse, mutect2, varscan2
- LRRC53 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs937695676, COSV53946315; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 25/71 reads (35%) | catalogued as rs1321319432; called by mutect2, pindel, varscan2
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 78/183 reads (43%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MAP4K4 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56336408; called by muse, mutect2, varscan2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NCSTN | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs201760425; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 145/397 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NUP188 | c.4997C>T p.A1666V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs529060637, COSV65330012; called by muse, mutect2, varscan2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 23/75 reads (31%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 39/146 reads (27%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- P3H2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1310957916; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 29/84 reads (35%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA13 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs891112880, COSV56510270; called by muse, mutect2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs759495724; called by mutect2, varscan2
- PEAK1 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as rs538475609, COSV56935136; called by muse, mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 44/106 reads (42%) | catalogued as rs755089774; called by pindel, varscan2
- PLCB4 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as rs1347474766, COSV53807281; called by muse, mutect2, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV99605417; called by muse, mutect2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2, varscan2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PRUNE2 | c.3017A>G p.E1006G | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65042933; called by muse, mutect2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 115/259 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as rs1234606471; called by mutect2, varscan2
- RASIP1 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1472624137, COSV55808826; called by muse, mutect2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs763290832; called by mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SGF29 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs1324158167, COSV100187093, COSV57681012; called by muse, mutect2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 35/91 reads (38%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SLC4A4 | c.1135G>A p.V379I (on ENST00000264485 / NM_001098484.3; = p.V335I on NM_003759.4) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs781031046; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 29/117 reads (25%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 64/172 reads (37%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 84/157 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRIOBP | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as rs1328461856, CM154690; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TSPOAP1 | c.5552G>A p.R1851K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs769282338, COSV52116577; called by muse, mutect2, varscan2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- VSX2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886042716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 86/236 reads (36%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZBTB25 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1346746094; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFYVE27 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs927949688; called by muse, mutect2, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- AC004922.1 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AC013489.1 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 187/419 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 38/83 reads (46%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ADGRG7 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.339); called by muse, mutect2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- AL121845.3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 49/135 reads (36%) | called by mutect2, pindel, varscan2
- ARID1A | c.1079C>A p.A360E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); called by muse, mutect2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 58/146 reads (40%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- BTAF1 | c.3437del p.L1146Wfs*27 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNB2 | c.287G>A p.R96H (on ENST00000324631 / NM_201596.3; = p.R41H on NM_000724.4) | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CATSPERE | c.1551A>G p.I517M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 37/94 reads (39%) | called by mutect2, pindel, varscan2
- CCDC189 | c.204+2T>C p.X68_splice | Splice Site (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 45/127 reads (35%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 43/124 reads (35%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.3473C>T p.A1158V (on ENST00000651564; = p.A1111V on NM_015692.5) | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 45/118 reads (38%) | called by mutect2, pindel, varscan2
- CRAT | c.1867del p.R623Gfs*47 | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 14/34 reads (41%) | called by pindel, varscan2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 47/154 reads (31%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DIP2A | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAH9 | c.4961T>C p.L1654P | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNAJC6 | c.2393del p.K798Rfs*6 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EFCAB5 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ENKD1 | c.882C>T p.S294= | Splice Region (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- EPC2 | c.2086C>T p.L696F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- FAM124A | c.1250G>A p.G417D (on ENST00000322475 / NM_001242312.2; = p.G453D on NM_145019.4) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM53C | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | called by pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GFRA4 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GMNN | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPHN | c.1382G>A p.G461D (on ENST00000315266 / NM_001377519.1; = p.G494D on NM_020806.5) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAGHL | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 12/414 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HHLA1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by pindel, varscan2
- HMCN1 | c.10119G>T p.Q3373H | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); called by muse, mutect2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- HYDIN | c.12622A>C p.N4208H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 55/143 reads (38%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 23/53 reads (43%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 9/83 reads (11%) | called by mutect2, pindel, varscan2
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 60/166 reads (36%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 45/131 reads (34%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- JMJD4 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 38/445 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); called by muse, mutect2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KCNC4 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- KDM2B | c.2594del p.F865Sfs*69 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMP1 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 45/126 reads (36%) | called by mutect2, pindel, varscan2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- LRRC73 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 72/200 reads (36%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- NKG7 | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRTN | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 53/121 reads (44%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | called by mutect2, pindel, varscan2
- OR2C1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 69/199 reads (35%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA13 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PLEKHF1 | c.814del p.V272Wfs*88 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 124/224 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 48/140 reads (34%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- PRR14L | c.5514del p.K1838Nfs*16 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBL1 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPK3 | c.1092del p.K364Nfs*69 | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | called by mutect2, pindel, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SAG | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 41/47 reads (87%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- SI | c.2078A>G p.Y693C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A5 | c.1555C>A p.R519S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SRCAP | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- STK35 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 48/132 reads (36%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TARBP2 | c.176A>G p.Q59R (on ENST00000266987 / NM_134323.2; = p.Q38R on NM_004178.4) | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCP11X1 | c.832del p.A278Qfs*19 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- TENT5A | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); called by muse, mutect2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- TJAP1 | c.1237A>C p.S413R (on ENST00000372445 / NM_001146016.1; = p.S403R on NM_080604.3) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 51/137 reads (37%) | called by mutect2, pindel, varscan2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM35 | c.1403del p.G468Vfs*129 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 10/33 reads (30%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 42/111 reads (38%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TWF1 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.4130G>T p.S1377I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF438 | c.2085G>T p.Q695H | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ACSF3 | c.1197C>T p.C399= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs768148002; ClinVar: likely benign; called by muse, mutect2, varscan2
- AFF2 | c.1902T>C p.V634= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs1016884567; called by muse, mutect2, varscan2
- ARID1A | c.1077C>T p.H359= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BICRA | c.3603C>T p.Y1201= | Silent (SNP) | VAF 23/228 reads (10%) | catalogued as rs1177638988; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 69/176 reads (39%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 66/161 reads (41%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CCDC8 | c.345C>T p.D115= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs1290525774; called by muse, mutect2, varscan2
- CCNB3 | c.2943C>T p.A981= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV52078472; called by muse, mutect2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 151/337 reads (45%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 61/116 reads (53%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 45/114 reads (39%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 68/206 reads (33%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CUBN | c.10632T>C p.P3544= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs771383564; called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DTX3L | c.2004G>A p.K668= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs181955910; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 77/190 reads (41%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13278C>T p.D4426= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as rs777098264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK1B | c.1167G>A p.R389= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- EPHX2 | c.1077T>C p.N359= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- EXOC8 | c.234C>T p.S78= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as rs1359130552; called by muse, mutect2
- FCHSD1 | c.1398G>A p.T466= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs775880422; called by muse, mutect2, varscan2
- FGR | c.1005G>A p.E335= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 64/230 reads (28%) | called by muse, mutect2, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HEPACAM | c.381C>T p.T127= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs766390439, COSV53432420; called by muse, mutect2, varscan2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 77/167 reads (46%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 69/120 reads (58%) | called by muse, mutect2, varscan2
- KCNJ16 | c.630C>T p.H210= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs199847474; called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KDM6B | c.2851C>A p.R951= | Silent (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- KRT6A | c.592C>T p.L198= | Silent (SNP) | VAF 39/297 reads (13%) | catalogued as rs1398015289; called by muse, mutect2, varscan2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 110/292 reads (38%) | called by muse, mutect2, varscan2
- LZTR1 | c.1425G>A p.T475= | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as rs140414846; called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NOVA2 | c.996C>T p.G332= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 82/204 reads (40%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- OR3A3 | c.408C>T p.C136= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV52166789; called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 64/196 reads (33%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- PAG1 | c.1026C>A p.T342= | Silent (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 63/150 reads (42%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV53370990, COSV53372538; called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 65/162 reads (40%) | called by muse, mutect2, varscan2
- PCDHA12 | c.201G>A p.A67= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as COSV56475835; called by muse, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1665C>T p.N555= | Silent (SNP) | VAF 20/372 reads (5%) | catalogued as rs782725222, COSV50753531, COSV99176308; called by muse, mutect2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PICK1 | c.1161G>A p.E387= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as rs1266755272; called by mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 125/283 reads (44%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLEKHA6 | c.2760T>C p.T920= | Silent (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- PRR14L | c.4794C>T p.C1598= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 86/191 reads (45%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RETN | c.303G>A p.A101= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99679342; called by muse, mutect2
- RPS6KA4 | c.2046G>A p.S682= | Silent (SNP) | VAF 25/189 reads (13%) | called by muse, mutect2, varscan2
- RTP5 | c.183G>A p.G61= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV58320097; called by muse, mutect2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 66/176 reads (38%) | called by muse, varscan2
- SGIP1 | c.2016C>T p.D672= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1320237507; called by muse, mutect2
- SIPA1L1 | c.4056A>G p.S1352= | Silent (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- SLC22A9 | c.1249C>T p.L417= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as rs1478775618; called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 92/169 reads (54%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SPTBN5 | c.8577C>T p.C2859= | Silent (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2
- TMPRSS12 | c.300C>T p.G100= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV68256446; called by muse, mutect2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 57/114 reads (50%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- TTN | c.66714T>G p.A22238= (on ENST00000591111; = p.A14814= on NM_003319.4) | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 55/177 reads (31%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 70/188 reads (37%) | called by muse, mutect2, varscan2
- VPS18 | c.1173G>A p.V391= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- WDR62 | c.966C>A p.A322= | Silent (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 127/316 reads (40%) | called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- AC068587.7 | n.128G>T | RNA (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 45/97 reads (46%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 92/448 reads (21%) | called by muse, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 83/234 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- AZIN2 | c.917-28G>A | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as rs1383985581; called by muse, mutect2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 47/119 reads (39%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3268dup | Intron (INS) | VAF 20/76 reads (26%) | called by mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 19/53 reads (36%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- CLEC4A | c.299-906dup | Intron (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 53/236 reads (22%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 63/230 reads (27%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- DCHS2 | n.1644G>A | RNA (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 54/152 reads (36%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 55/142 reads (39%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 16/39 reads (41%) | catalogued as rs1446348498; called by mutect2, pindel
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 41/75 reads (55%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 44/114 reads (39%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- GTF3C2 | c.1732+9del | Intron (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- HERC2P3 | n.768G>A | RNA (SNP) | VAF 19/124 reads (15%) | catalogued as rs761831955; called by muse, mutect2, varscan2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 75/197 reads (38%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- IKZF1 | c.161-8322del | Intron (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 19/48 reads (40%) | catalogued as COSV67183745; called by mutect2, varscan2
- KRT8P11 | n.1365G>A | RNA (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 49/124 reads (40%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs767804788; called by muse, mutect2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 46/100 reads (46%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MORC2 | chr22:30922485 G>A | 3'Flank (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- MTSS1 | c.1404+38T>C | Intron (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 6/13 reads (46%) | catalogued as rs746639059; called by mutect2, varscan2
- MUC19 | c.271-7del | Intron (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 36/157 reads (23%) | catalogued as rs1305952989, COSV58516256; called by muse, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 32/78 reads (41%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 9/46 reads (20%) | catalogued as rs749732874; called by mutect2, pindel
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- ODAPH | c.*38del | 3'UTR (DEL) | VAF 14/108 reads (13%) | catalogued as rs763292297; called by mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 12/49 reads (24%) | catalogued as rs771823733; called by mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 102/262 reads (39%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 35/102 reads (34%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 36/86 reads (42%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 32/106 reads (30%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 24/93 reads (26%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2
- POLM | c.714+75C>A | Intron (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- POU2F2 | c.303+365G>T | Intron (SNP) | VAF 15/97 reads (15%) | catalogued as rs368244459; called by muse, mutect2, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 34/144 reads (24%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2
- RNU7-115P | chr17:64822019 G>A | 3'Flank (SNP) | VAF 14/138 reads (10%) | called by mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 24/71 reads (34%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- RPS15 | c.90-32G>A | Intron (SNP) | VAF 38/256 reads (15%) | called by muse, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 92/224 reads (41%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 53/200 reads (27%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- TPRXL | n.752C>T | RNA (SNP) | VAF 18/110 reads (16%) | catalogued as rs192562800; called by muse, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 18/43 reads (42%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 12/32 reads (38%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 9/46 reads (20%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
